Somatic mutation profile of tumor specimen 0DIMWW from CCDI case PBBVKI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant tumor, spindle cell type; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.7 years (4,269 days).
Specimen 0DIMWW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf65b465-de23-432c-ae1c-4888d7a10eb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIMWJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/150768ff-49af-413a-8607-2500dcc495c7

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN15 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 28/344 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1362676989; called by muse, mutect2
- ZSWIM3 | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 98/257 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs201321759; called by muse, mutect2, varscan2
- RAP1GAP2 | c.2107G>A p.D703N | Missense Mutation (SNP) | VAF 13/288 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
